Somatic mutation profile of tumor specimen 0DKSZA from CCDI case PBBYPY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,791 days).
Specimen 0DKSZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb5f3af1-6387-442a-be63-312274bc289a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKSTT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2368d3ef-0096-4fa4-be84-c73fcd3e1252

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 237/543 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs747843638, COSV63972173; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDAC9 | c.1939G>A p.V647I | Missense Mutation (SNP) | VAF 106/691 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs768179213, COSV67775733; called by muse, mutect2, varscan2
- HS3ST3A1 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 43/774 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs866889757; called by muse, mutect2
- MYO1A | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 63/816 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141039063; called by muse, mutect2
- PCDHA5 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 192/577 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.587); catalogued as rs1489857640, COSV65349480; called by muse, mutect2, varscan2
- PTPRM | c.2746G>A p.D916N | Missense Mutation (SNP) | VAF 186/551 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV59843669; called by muse, mutect2, varscan2
- SCRN2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 40/702 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs552628767; called by muse, mutect2
- SLC1A6 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1364120285, COSV55667975, COSV55672668; called by muse, mutect2
- TGM5 | c.1108G>A p.V370I (on ENST00000220420 / NM_201631.4; = p.V288I on NM_004245.4) | Missense Mutation (SNP) | VAF 167/396 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs200175407, COSV55010657; called by muse, mutect2, varscan2
- GRIP1 | c.3146A>G p.D1049G (on ENST00000359742 / NM_001379345.1; = p.D997G on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/558 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEATR5A | c.4949A>G p.K1650R | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCGF2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- SPON1 | c.782A>G p.E261G | Missense Mutation (SNP) | VAF 40/875 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH5 | c.12591G>A p.E4197= | Silent (SNP) | VAF 51/706 reads (7%) | called by muse, mutect2
- HOXD4 | c.735C>T p.A245= | Silent (SNP) | VAF 17/645 reads (3%) | called by muse, mutect2
- OR4F6 | c.270G>A p.K90= | Silent (SNP) | VAF 40/490 reads (8%) | called by muse, mutect2
- SLITRK2 | c.2184A>G p.E728= | Silent (SNP) | VAF 15/303 reads (5%) | called by muse, mutect2
- NUDT16L1 | c.414+17G>A | Intron (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
